CPTAC case C3N-02088 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/028061ef-a99c-42dd-b011-344036e5357f

Demographics
Sex at birth: male; Race: asian; Year of birth: 1957; Vital status: Alive; Country of birth: Vietnam.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Lung, NOS; Age at diagnosis: 60.3 years (22,039 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: Tumor free; Days to last known disease status: 430 days (1.2 years); Progression or recurrence: no; Days to last follow up: 430 days (1.2 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm (a second GDC size field records 3 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 11; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 430 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 430 days (1.2 years); Disease response: Complete Response; Karnofsky performance status: 70; ECOG performance status: 2.

Other clinical attributes
- Weight: 50 kg; Height: 156 cm; BMI: 20.55.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 7.5; Cigarettes per day: 5; Tobacco smoking onset year: 1987; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 35.

Biospecimens (9 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-02088-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 270 mg.
- Samples C3N-02088-02, C3N-02088-03 (2 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 260 mg.
- Sample C3N-02088-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 250 mg; Time between clamping and freezing: 20 minutes; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-02088-24: Section location: Lung; Percent tumor nuclei: 70; Percent necrosis: 2.
- Sample C3N-02088-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 250 mg.
- Sample C3N-02088-07: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 7 days; Initial weight: 260 mg; Time between clamping and freezing: 22 minutes; Time between excision and freezing: 6 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3N-02088-31, C3N-02088-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-02088-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 7 days; Method of sample procurement: Blood Draw.
